Somatic mutation profile of tumor specimen TCGA-NK-A5CX-01A (aliquot TCGA-NK-A5CX-01A-11D-A26M-08) from TCGA case TCGA-NK-A5CX, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.6 years (26,879 days).
Specimen TCGA-NK-A5CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de4f5a08-53cd-4d76-a01e-0954c671d374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NK-A5CX-10A (Blood Derived Normal), aliquot TCGA-NK-A5CX-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b0228f8-665a-4412-9a8a-3f23e20721e0

The open-access MAF lists 182 somatic variants for this specimen: 140 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 38, Nonsense Mutation 8, Frame Shift Del 6, Splice Site 5, Translation Start Site 2, Splice Region 2, 5'Flank 1, Intron 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABI2 | c.656G>T p.R219L (on ENST00000295851 / NM_001375719.1; = p.R213L on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV53696660, COSV99652293; called by muse, mutect2, varscan2
- ADAM2 | c.186A>G p.Q62= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99697931; called by mutect2, varscan2
- ADAM29 | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV100822259; called by muse, mutect2, varscan2
- ADCY1 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV52037539, COSV52039184; called by muse, mutect2, varscan2
- ADGRB3 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101002014; called by muse, mutect2, varscan2
- AHCTF1 | c.6423G>T p.L2141F (on ENST00000366508; = p.L2115F on NM_015446.5) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100404466; called by muse, mutect2, varscan2
- AHNAK | c.5017G>C p.V1673L | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV99949732; called by muse, mutect2, varscan2
- AKAP4 | c.2172G>T p.L724F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV62075022; called by muse, mutect2, varscan2
- AKAP8L | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101275878; called by muse, mutect2, varscan2
- ALK | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101202756, COSV66555800; called by muse, mutect2, varscan2
- ANKEF1 | c.914G>C p.R305P | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV101000963, COSV101001076, COSV65693972; called by muse, mutect2, varscan2
- ARHGAP35 | c.3701G>C p.R1234P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV101351754; called by muse, mutect2, varscan2
- ATP7A | c.1335A>T p.S445= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100431756; called by muse, mutect2, varscan2
- BDKRB2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as rs763874568, COSV100021430; called by muse, mutect2
- BRINP3 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV100818460; called by muse, mutect2, varscan2
- BRWD1 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757972694, COSV60896704; called by muse, mutect2, varscan2
- C4orf50 | c.263G>T p.R88M (on ENST00000324058; = p.R1320M on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100136189; called by muse, mutect2
- CADPS2 | c.2959A>T p.I987F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV100466106; called by muse, mutect2, varscan2
- CCDC170 | c.1993G>C p.V665L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV99498888; called by muse, mutect2, varscan2
- CD4 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV99163921; called by muse, mutect2, varscan2
- CDC20 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60522439; called by muse, mutect2, varscan2
- CFTR | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs397508620, CM003260, COSV99140006; ClinVar: not provided; called by mutect2, varscan2
- CKM | c.1049T>G p.V350G | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53462439, COSV99488901; called by muse, mutect2, varscan2
- CNGB3 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV60700316; called by muse, mutect2, varscan2
- CPSF6 | c.867G>T p.L289F | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV99879699; called by muse, mutect2, varscan2
- DCUN1D4 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); catalogued as rs758053478, COSV100584725; called by muse, mutect2, varscan2
- DDX18 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99604831; called by muse, mutect2
- DIP2A | c.2395G>C p.D799H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100596352; called by muse, mutect2
- DLGAP1 | c.1954A>T p.I652F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100233926; called by muse, mutect2, varscan2
- DNAH5 | c.6515A>T p.N2172I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99454528; called by muse, mutect2, varscan2
- DNAH7 | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100417732; called by muse, mutect2
- DNAJC21 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100331606, COSV57761059; called by muse, mutect2, varscan2
- EFCAB6 | c.4384-1G>A p.X1462_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99414485; called by muse, mutect2, varscan2
- ENOPH1 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs200786339, COSV56731568; called by muse, mutect2, varscan2
- ENPP2 | c.2473G>C p.A825P (on ENST00000075322 / NM_001040092.3; = p.A877P on NM_006209.5) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309449; called by muse, mutect2, varscan2
- FAM135B | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs773432227, COSV99358272; called by muse, mutect2
- FFAR3 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588314; called by muse, mutect2, varscan2
- FGF14 | c.157A>T p.M53L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV101087689; called by muse, mutect2, varscan2
- FLG | c.6851C>A p.S2284Y | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs775430967, COSV100912037; called by muse, mutect2, varscan2
- FLG | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 122/475 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100912267; called by muse, mutect2, varscan2
- FNBP4 | c.728G>T p.W243L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771999; called by muse, mutect2, varscan2
- FSTL5 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV100061570; called by muse, mutect2, varscan2
- GP2 | c.490T>A p.Y164N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221667; called by muse, mutect2, varscan2
- GPHN | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100017831; called by muse, mutect2, varscan2
- GPR4 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547219; called by muse, mutect2, varscan2
- GUCY2C | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.241); catalogued as COSV99664184; called by muse, mutect2, varscan2
- H3C7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV99769285; called by muse, mutect2, varscan2
- HCN1 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100299249, COSV100301532; called by muse, mutect2, varscan2
- HDAC6 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV100491285; called by muse, mutect2
- HGF | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV55952401, COSV99738620; called by muse, mutect2
- HSPA6 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100554353, COSV59059783; called by muse, mutect2, varscan2
- HSPBP1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55334062, COSV99729292; called by muse, mutect2
- IGKV1D-43 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573204545; called by muse, mutect2, varscan2
- IGKV3-20 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs753252802; called by muse, mutect2
- IL9R | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99730263; called by muse, mutect2
- INPPL1 | c.1714A>G p.R572G | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996680; called by muse, mutect2, varscan2
- ITGAE | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99561575; called by muse, mutect2, varscan2
- ITIH6 | c.2807C>A p.P936H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV99514003; called by muse, mutect2, varscan2
- KALRN | c.6400C>A p.L2134M (on ENST00000360013 / NM_001024660.4; = p.L437M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.373); catalogued as COSV99363042; called by muse, mutect2, varscan2
- KCNH1 | c.2595G>T p.R865S (on ENST00000271751 / NM_172362.3; = p.R838S on NM_002238.4) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); catalogued as rs1345202329, COSV99661654; called by muse, mutect2, varscan2
- KIAA0100 | c.4415G>T p.G1472V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV101197427; called by muse, mutect2, varscan2
- KIR3DX1 | n.956-1G>A | Splice Site (SNP) | VAF 12/80 reads (15%) | catalogued as COSV55597794, COSV99683691; called by muse, varscan2
- KLHL1 | c.72C>A p.H24Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100918196, COSV100918332, COSV64772371; called by muse, mutect2
- LAMA1 | c.2399A>G p.N800S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs996072933, COSV101057837; called by muse, mutect2, varscan2
- LOXL3 | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99284223; called by muse, mutect2, varscan2
- LRRIQ3 | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV100598527, COSV100599519; called by muse, mutect2, varscan2
- LRRK2 | c.3647A>T p.H1216L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100111201; called by muse, mutect2, varscan2
- MAGEC1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.944); catalogued as COSV53569627; called by muse, mutect2, varscan2
- MAGEL2 | c.2918C>A p.P973Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100046242; called by muse, mutect2, varscan2
- MINDY4 | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99519323; called by muse, mutect2, varscan2
- MROH2B | c.4498G>T p.E1500* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV101270938, COSV68186181; called by muse, mutect2, varscan2
- MROH2B | c.4497G>T p.Q1499H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV101270877; called by muse, mutect2, varscan2
- MROH2B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1407999857, COSV68182448; called by muse, mutect2, varscan2
- MROH2B | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV101270939; called by muse, mutect2, varscan2
- MYH2 | c.4082C>A p.A1361D | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs746987339, COSV99821025; called by muse, mutect2, varscan2
- MYO7B | c.4912C>A p.R1638S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV67349269; called by mutect2, varscan2
- NAPG | c.819G>C p.L273F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100529939; called by muse, mutect2, varscan2
- NAV3 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99889881, COSV99895988; called by muse, mutect2, varscan2
- NBAS | c.1811A>G p.Q604R | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); catalogued as rs747209092, COSV99871711; called by muse, mutect2, varscan2
- NLRP7 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.057); catalogued as CM1210280, COSV100053411; called by muse, mutect2, varscan2
- NPC1L1 | c.3368+1G>T p.X1123_splice | Splice Site (SNP) | VAF 19/165 reads (12%) | catalogued as COSV99213597; called by muse, mutect2, varscan2
- ODF3L2 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV99199225; called by muse, mutect2, varscan2
- OR2G3 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as COSV100180795, COSV60680774; called by muse, mutect2, varscan2
- OR51D1 | c.722T>A p.L241Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914251; called by muse, mutect2, varscan2
- OR56A1 | c.791C>G p.T264R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100360566; called by muse, mutect2, varscan2
- OR5AP2 | c.942C>A p.H314Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100266457, COSV57258422; called by muse, mutect2, varscan2
- OR5T3 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100282946, COSV57381541; called by muse, mutect2, varscan2
- OSBPL2 | c.547A>G p.S183G (on ENST00000313733 / NM_144498.4; = p.S171G on NM_014835.4) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100569352; called by muse, mutect2, varscan2
- PAPOLB | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV101271627; called by muse, mutect2
- PAPPA2 | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100868706; called by muse, mutect2, varscan2
- PARD3B | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100595394, COSV62514491; called by muse, mutect2, varscan2
- PCDHB4 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1554274693, COSV52027361; called by muse, mutect2
- PCDHB5 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV99169625; called by muse, mutect2, varscan2
- PEAR1 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757661147, COSV99440391, COSV99442448; called by muse, mutect2, varscan2
- PIK3R1 | c.1738_1745+2del p.X580_splice (on ENST00000521381 / NM_181523.3; = p.X310_splice on NM_181504.4) | Splice Site (DEL) | VAF 12/76 reads (16%) | catalogued as COSV57123887; called by mutect2, pindel, varscan2
- PKHD1L1 | c.1440G>C p.Q480H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV101006874; called by muse, mutect2, varscan2
- PKN2 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100281786; called by muse, mutect2, varscan2
- POSTN | c.2180-1G>T p.X727_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV101123505; called by muse, mutect2, varscan2
- POSTN | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101123506; called by muse, mutect2
- PPAN-P2RY11 | c.987G>T p.Q329H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461863; called by muse, mutect2, varscan2
- PROKR2 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99450669; called by muse, mutect2, varscan2
- PROS1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as CM163616, COSV101260858, COSV67775570; called by muse, mutect2, varscan2
- PXDNL | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100686557, COSV62476887; called by muse, mutect2, varscan2
- RAB40AL | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99505298; called by mutect2, varscan2
- RADIL | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as rs777510897, COSV101271626; called by muse, mutect2, varscan2
- RBCK1 | c.533C>T p.P178L (on ENST00000356286 / NM_031229.4; = p.P136L on NM_006462.6) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100675986; called by muse, mutect2, varscan2
- RECQL4 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99468280; called by muse, mutect2
- RNF17 | c.861G>T p.R287S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99694482; called by muse, mutect2, varscan2
- ROCK2 | c.1702A>G p.N568D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV99837914; called by muse, mutect2, varscan2
- RYR1 | c.10979C>T p.A3660V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100617097; called by muse, mutect2, varscan2
- RYR2 | c.9656T>C p.V3219A | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.066); catalogued as COSV100773095; called by muse, mutect2, varscan2
- RYR2 | c.12340C>T p.R4114* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as rs1430428297, COSV100773096; called by muse, mutect2, varscan2
- SHROOM4 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99174773; called by muse, mutect2
- SIGLEC10 | c.539G>T p.W180L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59478685; called by muse, mutect2, varscan2
- SLC22A11 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100102719; called by muse, mutect2, varscan2
- SLU7 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99775851; called by muse, mutect2, varscan2
- SNRPN | c.129T>A p.C43* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100578671; called by muse, mutect2, varscan2
- SPTA1 | c.3238C>A p.Q1080K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV100935627; called by muse, mutect2, varscan2
- SYNDIG1L | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as COSV100526599; called by muse, mutect2, varscan2
- TBL1Y | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100667368; called by muse, mutect2, varscan2
- TCHHL1 | c.2213C>A p.T738K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.175); catalogued as rs774720731, COSV100916621; called by muse, mutect2, varscan2
- TRPM2 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100309354, COSV55970076; called by muse, mutect2, varscan2
- TSPAN18 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100418969; called by muse, mutect2, varscan2
- TTN | c.84508T>C p.S28170P (on ENST00000591111; = p.S20746P on NM_003319.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | PolyPhen possibly damaging (0.804); catalogued as COSV100631459; called by muse, mutect2, varscan2
- TTN | c.57986C>A p.P19329Q (on ENST00000591111; = p.P11905Q on NM_003319.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV100589341; called by muse, mutect2
- UGT2A3 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99280233; called by muse, mutect2, varscan2
- USF3 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV100325836; called by muse, mutect2, varscan2
- UTRN | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV100839806, COSV100840673; called by muse, varscan2
- ZC3H12A | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897782; called by muse, mutect2, varscan2
- ZCCHC2 | c.1978A>T p.T660S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV99502689; called by muse, mutect2
- ZNF106 | c.3210G>T p.M1070I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV99783217; called by muse, mutect2, varscan2
- CGB7 | c.144del p.V49Sfs*13 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, varscan2
- CGN | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.073); called by muse, mutect2
- DNAH7 | c.2552_2553del p.P851Qfs*19 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- LAMB4 | c.2476del p.D826Tfs*7 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- NINL | c.552del p.S185Afs*32 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel*, varscan2
- P2RY8 | c.81del p.V28Wfs*35 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- RASL10B | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZBTB16 | c.848del p.P283Rfs*64 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by pindel, varscan2
- AP002512.3 | c.534C>A p.S178= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54407000, COSV99688142; called by muse, mutect2
- AQP12B | c.312G>T p.A104= (on ENST00000621682; = p.A116= on NM_001102467.2) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101315945; called by muse, mutect2, varscan2
- ATP13A2 | c.2967G>T p.R989= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100454468; called by muse, mutect2, varscan2
- BCAS2 | c.666G>T p.R222= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV101058670; called by muse, mutect2
- BTNL3 | c.1197C>A p.P399= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100732255; called by muse, mutect2, varscan2
- CDH18 | c.1710C>A p.I570= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99938558; called by muse, mutect2, varscan2
- CDHR5 | c.2091C>A p.G697= (on ENST00000358353 / NM_001171968.2; = p.G703= on NM_021924.5) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100363841; called by muse, mutect2, varscan2
- CDHR5 | c.339A>T p.S113= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99449335; called by muse, mutect2, varscan2
- COL4A4 | c.1050G>T p.G350= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100307763; called by muse, mutect2
- CYP2C9 | c.303A>G p.P101= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs1360621366, COSV99583254; called by muse, mutect2, varscan2
- EIF2AK3 | c.1299C>T p.P433= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100304142; called by muse, mutect2, varscan2
- EIF4H | c.276G>T p.V92= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99733690; called by muse, mutect2
- FAM83C | c.2052C>T p.T684= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs866254663, COSV100981720; called by muse, mutect2, varscan2
- FFAR3 | c.720C>A p.P240= | Silent (SNP) | VAF 35/236 reads (15%) | catalogued as COSV100588315; called by muse, mutect2, varscan2
- FILIP1L | c.387C>A p.T129= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100497397; called by muse, mutect2, varscan2
- FLG | c.6678C>A p.G2226= | Silent (SNP) | VAF 74/326 reads (23%) | catalogued as COSV100910670, COSV64246972; called by muse, mutect2, varscan2
- GOLGB1 | c.9294A>G p.Q3098= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs757555589, COSV100511572; called by muse, mutect2, varscan2
- HSF2 | c.507A>T p.A169= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100869740; called by muse, mutect2, varscan2
- IL1R2 | c.138A>G p.V46= | Silent (SNP) | VAF 42/225 reads (19%) | catalogued as COSV100208279; called by muse, mutect2, varscan2
- KIAA0100 | c.4416G>T p.G1472= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV101197426; called by muse, mutect2, varscan2
- KMO | c.465C>G p.P155= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100844820, COSV63809876; called by muse, mutect2
- MACF1 | c.14676T>A p.L4892= (on ENST00000372915; = p.L2825= on NM_012090.5) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV99247031; called by muse, mutect2, varscan2
- MAGEC3 | c.789T>C p.S263= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100026152; called by muse, mutect2, varscan2
- MAPK1 | c.912A>G p.V304= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1449348419, COSV99308221; called by muse, mutect2, varscan2
- MUC17 | c.6543T>C p.L2181= | Silent (SNP) | VAF 55/469 reads (12%) | catalogued as COSV100075155; called by muse, mutect2, varscan2
- PKD1 | c.11097C>T p.Y3699= (on ENST00000262304 / NM_001009944.3; = p.Y3698= on NM_000296.4) | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as rs778200179, COSV99239100; called by muse, mutect2, varscan2
- PKHD1L1 | c.7827C>A p.G2609= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV101006875, COSV65746392; called by muse, mutect2, varscan2
- PLBD2 | c.1164G>A p.P388= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs750819854, COSV99785531; called by muse, mutect2, varscan2
- PTPRN | c.312T>C p.Y104= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99834379; called by muse, mutect2, varscan2
- SCTR | c.1158C>T p.V386= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99191756; called by muse, mutect2, varscan2
- SETBP1 | c.336G>T p.R112= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV99955110; called by muse, mutect2
- SHKBP1 | c.1938G>T p.G646= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99182945, COSV99199659; called by muse, mutect2, varscan2
- SPTA1 | c.3237G>A p.L1079= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100935628; called by muse, mutect2, varscan2
- STAMBP | c.591G>T p.V197= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100277812; called by muse, mutect2, varscan2
- TFAP2B | c.228G>A p.P76= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV53829969, COSV99540676; called by muse, mutect2, varscan2
- TRIM33 | c.1974C>T p.T658= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100635790; called by muse, mutect2, varscan2
- TTN | c.77919G>A p.A25973= (on ENST00000591111; = p.A18549= on NM_003319.4) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs370505439; ClinVar: likely benign; called by muse, varscan2
- WFS1 | c.1911G>C p.L637= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as COSV99901633; called by muse, mutect2, varscan2
- OR8G5 | c.-14-24C>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100422683; called by muse, mutect2, varscan2
- SERPINA13P | n.745A>G | RNA (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134177669 A>G | 5'Flank (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99399216; called by muse, mutect2, varscan2
- ZNF99 | c.*292G>T | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as COSV68056166; called by muse, mutect2, varscan2
